Somatic mutation profile of tumor specimen TCGA-B2-4098-01A (aliquot TCGA-B2-4098-01A-02D-1386-10) from TCGA case TCGA-B2-4098, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 72.8 years (26,606 days).
Specimen TCGA-B2-4098-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4e8ab66-1534-41d5-b0eb-d882436ff480.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-4098-10A (Blood Derived Normal), aliquot TCGA-B2-4098-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/342fcf9e-3f03-4642-b507-ef06eb4ee3bd

The open-access MAF lists 62 somatic variants for this specimen: 45 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 16, Frame Shift Del 8, Frame Shift Ins 3, Nonsense Mutation 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.246A>C p.E82D | Missense Mutation (SNP) | VAF 98/503 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- SPINK5 | c.2468del p.K823Rfs*101 | Frame Shift Del (DEL) | VAF 121/696 reads (17%) | catalogued as rs565782662; ClinVar: pathogenic; called by mutect2, varscan2
- ALOXE3 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as rs1429783354, COSV58554571; called by muse, mutect2, varscan2
- AP3S1 | c.28A>C p.N10H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV57242869; called by muse, mutect2
- APOBEC3B | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763640667, COSV59840543; called by muse, mutect2, varscan2
- ARHGAP28 | c.1060T>G p.F354V (on ENST00000383472 / NM_001366230.1; = p.F195V on NM_001010000.3) | Missense Mutation (SNP) | VAF 106/433 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51634082; called by mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 33/198 reads (17%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- C22orf42 | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.291); catalogued as COSV66075569; called by muse, mutect2
- C2orf88 | c.38C>G p.P13R | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV61409901; called by muse, mutect2
- CIB4 | c.350T>C p.I117T | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs774551970, COSV56599859; called by muse, mutect2, varscan2
- CORO1A | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1446315301, COSV54630764; called by muse, mutect2
- CSTF3 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 71/342 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV60610171; called by muse, mutect2, varscan2
- DGKZ | c.3199G>A p.V1067M (on ENST00000454345 / NM_001105540.2; = p.V879M on NM_003646.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs540339132, COSV58986401; called by muse, varscan2
- DUOX1 | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as COSV58478772; called by muse, mutect2
- ELK4 | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56984278; called by muse, mutect2, varscan2
- GLB1 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56562430; called by muse, mutect2, varscan2
- HEXA | c.796T>G p.W266G | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM126853, COSV51505690; called by muse, mutect2
- ILKAP | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs573048716, COSV54517700, COSV54518783; called by muse, mutect2, varscan2
- ITGAL | c.1799C>A p.A600D | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV63320906, COSV63323898; called by muse, mutect2, varscan2
- KIF4B | c.1256G>T p.R419M | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV70528455, COSV70529222; called by muse, mutect2, varscan2
- KRTAP4-4 | c.375C>A p.Y125* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV66811265, COSV66811382; called by muse, mutect2, varscan2
- LINS1 | c.1790C>A p.P597H | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); catalogued as COSV59078297; called by muse, mutect2, varscan2
- MEPCE | c.2035T>A p.Y679N | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV52768871; called by muse, mutect2, varscan2
- MTMR4 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60199789; called by muse, mutect2, varscan2
- NCKAP5L | c.1427T>G p.L476R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV60128292; called by muse, mutect2, varscan2
- NRROS | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV60745131; called by muse, mutect2, varscan2
- RPN1 | c.802A>T p.R268* | Nonsense Mutation (SNP) | VAF 42/218 reads (19%) | catalogued as COSV56189395; called by muse, mutect2, varscan2
- SKIL | c.2014A>C p.K672Q | Missense Mutation (SNP) | VAF 76/354 reads (21%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.496); catalogued as COSV52058900; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 32/168 reads (19%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCAD1 | c.2124A>G p.I708M | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62773449; called by muse, mutect2, varscan2
- TSGA10IP | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV73245242; called by muse, varscan2
- TTN | c.41443G>A p.D13815N (on ENST00000591111; = p.D6391N on NM_003319.4) | Missense Mutation (SNP) | VAF 99/605 reads (16%) | PolyPhen probably damaging (0.998); catalogued as COSV59949282; called by muse, mutect2, varscan2
- UMPS | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51736572; called by muse, mutect2, varscan2
- YY1AP1 | c.875T>A p.L292Q (on ENST00000295566 / NM_139118.2; = p.L215Q on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/363 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55119864, COSV99803667; called by muse, mutect2, varscan2
- ZDHHC16 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.224); catalogued as COSV61748892; called by muse, mutect2, varscan2
- CIT | c.1192del p.S398Hfs*7 | Frame Shift Del (DEL) | VAF 24/145 reads (17%) | called by mutect2, pindel, varscan2
- CNOT4 | c.601_602dup p.N202Rfs*47 | Frame Shift Ins (INS) | VAF 64/383 reads (17%) | called by pindel, varscan2
- ERCC6L2 | c.4073A>T p.K1358I | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- KDM6A | c.3735del p.A1246Pfs*19 | Frame Shift Del (DEL) | VAF 88/356 reads (25%) | called by mutect2, pindel
- NBEA | c.5163del p.P1722Lfs*5 | Frame Shift Del (DEL) | VAF 27/185 reads (15%) | called by mutect2, pindel, varscan2
- NECTIN2 | c.1467dup p.V490Rfs*8 | Frame Shift Ins (INS) | VAF 18/102 reads (18%) | called by mutect2, pindel, varscan2
- SORBS2 | c.1504_1515del p.P502_M505del | In Frame Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- TRMT1L | c.1607del p.F536Sfs*24 | Frame Shift Del (DEL) | VAF 50/257 reads (19%) | called by mutect2, pindel, varscan2
- WDR73 | c.1095del p.L366Cfs*37 | Frame Shift Del (DEL) | VAF 33/168 reads (20%) | called by mutect2, pindel, varscan2
- ZNF804B | c.408dup p.A137Sfs*18 | Frame Shift Ins (INS) | VAF 17/77 reads (22%) | called by mutect2, pindel, varscan2
- ARG2 | c.33C>G p.L11= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs758755127, COSV55775637, COSV55776796; called by muse, mutect2, varscan2
- CAMSAP1 | c.3312G>A p.P1104= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs772630621, COSV56720383; called by muse, mutect2, varscan2
- GCNT2 | c.382C>T p.L128= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV65456841; called by muse, mutect2, varscan2
- GNMT | c.636G>A p.V212= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV55102377; called by muse, mutect2, varscan2
- GRIA2 | c.108C>T p.G36= | Silent (SNP) | VAF 36/250 reads (14%) | catalogued as COSV52385756; called by muse, mutect2, varscan2
- IGF2 | c.406C>T p.L136= (on ENST00000434045 / NM_001127598.3; = p.L80= on NM_000612.6) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV56097723, COSV56098878; called by muse, mutect2, varscan2
- OR2W3 | c.207G>T p.L69= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV64456382; called by muse, mutect2, varscan2
- PDGFRB | c.2664C>T p.S888= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as COSV55802739; called by muse, mutect2, varscan2
- POLDIP3 | c.666C>A p.S222= | Silent (SNP) | VAF 48/265 reads (18%) | catalogued as COSV52808564; called by muse, mutect2, varscan2
- PRTG | c.3294A>T p.T1098= | Silent (SNP) | VAF 46/234 reads (20%) | catalogued as COSV66837127; called by muse, mutect2, varscan2
- RPS20 | c.93C>T p.S31= | Silent (SNP) | VAF 29/173 reads (17%) | catalogued as rs1020995286, COSV50536278; called by muse, mutect2, varscan2
- RTN2 | c.933C>T p.T311= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs539287856, COSV55593207; called by muse, mutect2, varscan2
- SYBU | c.465C>T p.G155= (on ENST00000276646 / NM_001099754.2; = p.G154= on NM_017786.6) | Silent (SNP) | VAF 26/169 reads (15%) | catalogued as rs954713147, COSV52615504; called by muse, mutect2, varscan2
- TENM1 | c.867G>A p.S289= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as rs191615019, COSV64424601, COSV64427743; ClinVar: benign; called by muse, mutect2, varscan2
- XPO5 | c.3614G>A p.*1205= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as COSV54828492; called by muse, mutect2, varscan2
- ZPLD1 | c.36T>C p.I12= (on ENST00000466937 / NM_001329788.1; = p.I28= on NM_175056.2) | Silent (SNP) | VAF 117/487 reads (24%) | catalogued as COSV60352507; called by muse, mutect2, varscan2
- CRYL1 | c.*2T>C | 3'UTR (SNP) | VAF 21/133 reads (16%) | catalogued as COSV100004641; called by muse, mutect2, varscan2
